Somatic mutation profile of tumor specimen TCGA-27-2523-01A (aliquot TCGA-27-2523-01A-01D-1494-08) from TCGA case TCGA-27-2523, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.1 years (23,034 days).
Specimen TCGA-27-2523-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bcd1c73-f515-4747-89c9-7fcd8e60f502.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-27-2523-10A (Blood Derived Normal), aliquot TCGA-27-2523-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0d495a4-1503-45bc-a683-b9a296c7d3a3

The open-access MAF lists 51 somatic variants for this specimen: 41 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 36, Silent 10, Nonsense Mutation 3, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQP12B | c.250G>A p.V84M (on ENST00000621682; = p.V96M on NM_001102467.2) | Missense Mutation (SNP) | VAF 35/64 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs545420469, COSV68183941; called by muse, mutect2, varscan2
- AREG | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 49/92 reads (53%) | catalogued as rs1283640826; called by muse, mutect2, varscan2
- ARFGEF1 | c.3472A>G p.T1158A | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV51608269; called by muse, mutect2, varscan2
- CD163 | c.572A>T p.D191V | Missense Mutation (SNP) | VAF 236/574 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.345); catalogued as COSV63132164; called by muse, mutect2, varscan2
- CRY1 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs774995797, COSV50482643; called by muse, mutect2, varscan2
- CYP4F8 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs377226039; called by muse, mutect2, varscan2
- DCLK3 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 142/384 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.033); catalogued as COSV69362606; called by muse, mutect2, varscan2
- DGKZ | c.1219G>A p.V407M (on ENST00000454345 / NM_001105540.2; = p.V219M on NM_003646.4) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.411); catalogued as COSV58988180; called by muse, mutect2, varscan2
- DLG1 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.114); catalogued as COSV58382557; called by muse, mutect2, varscan2
- DOCK2 | c.5024C>T p.T1675M | Missense Mutation (SNP) | VAF 105/263 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.072); catalogued as rs201322810; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM126A | c.116C>A p.S39* | Nonsense Mutation (SNP) | VAF 40/180 reads (22%) | catalogued as COSV69016721, COSV69017090; called by muse, mutect2, varscan2
- FCER1A | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.77); PolyPhen benign (0.027); catalogued as COSV63667202, COSV63667832; called by muse, mutect2, varscan2
- HMCN1 | c.786T>A p.N262K | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV54899463; called by muse, mutect2, varscan2
- IGLV3-19 | c.182C>T p.A61V | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as rs760929043; called by muse, mutect2, varscan2
- KIRREL2 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs1179754685, COSV52876258; called by muse, mutect2, varscan2
- MYO1B | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs139382265; called by muse, mutect2, varscan2
- N4BP2 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); catalogued as rs780476202, COSV54699826; called by muse, mutect2, varscan2
- NAP1L1 | c.739T>G p.F247V | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53874450; called by muse, mutect2, varscan2
- NIT2 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 178/378 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs183950946, COSV67630147; called by muse, mutect2, varscan2
- OBSCN | c.1879G>A p.G627S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV52761679; called by muse, varscan2
- PAPPA | c.2725G>A p.V909I | Missense Mutation (SNP) | VAF 137/321 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs199874720, COSV60278234; called by muse, mutect2, varscan2
- PCDH10 | c.2875G>T p.V959F | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.541); catalogued as COSV52093636; called by muse, mutect2, varscan2
- PCDH11Y | c.3755C>T p.S1252F | Missense Mutation (SNP) | VAF 167/181 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as COSV53080596, COSV53085076; called by muse, mutect2, varscan2
- PCDH9 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 128/323 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV60549248; called by muse, mutect2, varscan2
- PEX5 | c.176A>G p.E59G | Missense Mutation (SNP) | VAF 91/211 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as COSV56954905; called by muse, mutect2, varscan2
- PGBD2 | c.1604G>A p.G535E | Missense Mutation (SNP) | VAF 62/146 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as COSV61400159; called by muse, mutect2, varscan2
- PGBD2 | c.1761G>T p.R587S | Missense Mutation (SNP) | VAF 82/155 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV61400166; called by muse, mutect2, varscan2
- PLPPR2 | c.500C>T p.T167M | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758235960, COSV52259888; called by muse, mutect2, varscan2
- PRSS36 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.826); catalogued as rs1388947260, COSV51637199; called by muse, mutect2, varscan2
- SLC17A7 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55547680; called by muse, mutect2, varscan2
- SLC39A4 | c.59C>T p.A20V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs782236196, COSV52778753; called by muse, mutect2, varscan2
- SLCO4A1 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.322); catalogued as rs373121417; called by muse, mutect2, varscan2
- SULF2 | c.101G>A p.R34K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.174); catalogued as rs1247809640, COSV63415869; called by muse, mutect2, varscan2
- TNFRSF11A | c.426G>A p.P142= | Splice Region (SNP) | VAF 39/94 reads (41%) | catalogued as rs139968917, COSV54023397; called by muse, mutect2, varscan2
- TRHDE | c.3001G>A p.E1001K | Missense Mutation (SNP) | VAF 72/144 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as rs1219010746, COSV53836177; called by muse, mutect2, varscan2
- TTN | c.28280G>A p.R9427H (on ENST00000591111; = p.R8500H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 151/327 reads (46%) | PolyPhen probably damaging (0.998); catalogued as rs760305440, CM094355, COSV60048835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBG1 | c.1027C>T p.R343C | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52221129; called by muse, mutect2, varscan2
- UGGT1 | c.4434G>A p.W1478* | Nonsense Mutation (SNP) | VAF 162/335 reads (48%) | catalogued as COSV52135574; called by muse, mutect2, varscan2
- UTP25 | c.60G>C p.Q20H | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV72227414; called by muse, varscan2
- WDR27 | c.1996A>G p.I666V | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV61208647; called by muse, mutect2, varscan2
- PIK3R2 | c.1553del p.M518Sfs*6 | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- DCLK2 | c.2067C>G p.V689= | Silent (SNP) | VAF 79/202 reads (39%) | catalogued as COSV56204177, COSV56209831; called by muse, mutect2, varscan2
- GABRQ | c.957C>T p.L319= | Silent (SNP) | VAF 120/128 reads (94%) | catalogued as COSV64781932; called by muse, mutect2, varscan2
- ITGA11 | c.2454C>T p.S818= | Silent (SNP) | VAF 7/11 reads (64%) | catalogued as rs376522259; called by muse, mutect2, varscan2
- KRTAP10-5 | c.162G>A p.A54= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as rs201287112, COSV59961634; called by muse, mutect2, varscan2
- LBX1 | c.384G>A p.S128= | Silent (SNP) | VAF 57/66 reads (86%) | catalogued as COSV64621772; called by muse, mutect2, varscan2
- LPCAT4 | c.1113G>A p.T371= | Silent (SNP) | VAF 56/151 reads (37%) | catalogued as rs1230448403, COSV59216734; called by muse, mutect2, varscan2
- MUC16 | c.43374C>T p.I14458= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as rs759749285, COSV66691888; called by muse, mutect2
- SETD1A | c.1323T>C p.G441= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV52687578; called by muse, mutect2, varscan2
- SLIT2 | c.2103C>T p.P701= | Silent (SNP) | VAF 82/196 reads (42%) | catalogued as COSV56571849; called by muse, mutect2, varscan2
- STYXL2 | c.3117C>A p.P1039= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV54804955; called by muse, mutect2, varscan2
